Surgical pathology report (de-identified scan), TCGA case TCGA-IK-8125, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Christiana Healthcare, specimen TCGA-IK-8125-01A (Primary Tumor).

DEPARTMENT OF PATHOLOGY AND LABORATORY MEDICINE

Date Coll: [REDACTED]

SURGICAL PATHOLOGY REPORT

Accession No.: [REDACTED]

SPECIMEN

- A. Brain tumor
- B. Brain tumor
- C. Brain tumor

CLINICAL NOTES

CLINICAL HISTORY: Left frontal brain tumor.

FROZEN SECTION DIAGNOSIS

FSA) Left frontal - At least anaplastic astrocytoma (WHO grade III). Final grade deferred to permanent sections.

FSB) Brain tumor - Predominantly glial, include rare microscopic involvement by tumor. [REDACTED]

GROSS DESCRIPTION

A. Received fresh for frozen section, labeled "brain tumor" are irregularly shaped fragments of hemorrhagic tissue that measure 1.5 x 1.2 x 0.6 cm. in dimension. Half of the specimen is frozen and the remainder is taken for permanent section. [REDACTED]

B. Received fresh for frozen section, labeled "brain tumor" is an irregularly shaped fragment of tan-white tissue that measures 0.2 x 0.2 x 0.2 cm. in dimension. The tissue is entirely frozen.

C. The specimen is received fresh, labeled "brain tumor-routine" and consists of multiple pieces of pink to soft yellow tissue measuring 1.0 cm. The tissue is entirely submitted. [REDACTED]

MICROSCOPIC DESCRIPTION

Microscopic sections of the left frontal brain tumor reveals a malignant diffuse glioma. The tumor does have diffuse high grade astrocytoma as suggested by the patient's prior core biopsy [REDACTED]. The current material, however, does have what appears to be oligodendroglial differentiation suggesting the lesion is actually a mixed glioma. For the [REDACTED] consultation [REDACTED] up to the [REDACTED]. [REDACTED] reviewed [REDACTED] and categorized it as an anaplastic oligoastrocytoma WHO grade III. They will be doing a FISH study for the 1p/19q deletion which is seen in oligodendrogliomas. That result will be reported separately.

DIAGNOSIS

A, B, C. Brain, left frontal, resection:

A

--- End Of Report ---

Source: NCI Genomic Data Commons file e5ec1b3b-c7e9-4604-b3c4-e8dff5b0405e (TCGA-IK-8125.77A2C310-8F8B-4E45-92D8-52379E34F11F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).